MMRF case MMRF_2307 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/78dc4445-f0c6-4102-8893-190085c26397

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.5 years (24,294 days); ISS stage: I; Days to last known disease status: 94 days; Days to last follow up: 94 days.
   Treatment given: Therapeutic agents: Bortezomib + Doxorubicin + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1 (ECOG 0): M Protein 2.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.32 mg/dL; Immunoglobulin G 35.6 g/L; Immunoglobulin A 0.97 g/L; Immunoglobulin M 0.437 g/L; Beta 2 Microglobulin 2.79 µg/mL; Lactate Dehydrogenase 4.22 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 6.14 ×10⁹/L; Absolute Neutrophil 3.59 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.5 mmol/L; Albumin 48.9 g/L; Total Protein 9.2 g/dL; C-Reactive Protein 0.04 mg/dL.
- Day 94 (ECOG 1): M Protein 3.91 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.412 mg/dL; Immunoglobulin G 4.61 g/L; Immunoglobulin A 0.452 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 7.38 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.03 ×10⁹/L; Absolute Neutrophil 2.73 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Total Protein 6.3 g/dL.

Other clinical attributes
- Day -1: Weight: 70 kg; Height: 161 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2307_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_2307_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
